Somatic mutation profile of tumor specimen TCGA-QK-A6II-01A (aliquot TCGA-QK-A6II-01A-11D-A31L-08) from TCGA case TCGA-QK-A6II, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 52.3 years (19,113 days).
Specimen TCGA-QK-A6II-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b5d9cd8-7d6d-4347-b37e-916e0d8b57f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A6II-10A (Blood Derived Normal), aliquot TCGA-QK-A6II-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31dd55d9-3684-4e85-be96-7fd1243b630a

The open-access MAF lists 193 somatic variants for this specimen: 145 protein-altering or splice-affecting, 44 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 44, Splice Site 4, Frame Shift Del 4, Nonsense Mutation 3, Splice Region 3, 3'UTR 1, Translation Start Site 1, In Frame Del 1, Intron 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>G p.R465G (on ENST00000281708 / NM_001349798.2; = p.R385G on NM_018315.5) | Missense Mutation (SNP) | VAF 26/139 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1397-1G>A p.X466_splice | Splice Site (SNP) | VAF 42/76 reads (55%) | catalogued as rs1553631693, CS064462, COSV55464532; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD1 | c.273G>C p.Q91H | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53205974, COSV53207729, COSV99574889; called by muse, mutect2, varscan2
- ACTG2 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV100609566; called by muse, mutect2, varscan2
- AGBL1 | c.1915G>A p.G639S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as rs180793760, COSV66863776; called by mutect2, varscan2
- AHNAK | c.7490A>G p.N2497S | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs750476532, COSV99950139; called by muse, mutect2, varscan2
- AJM1 | c.2049C>G p.F683L | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV99915957; called by muse, mutect2, varscan2
- ARHGAP15 | c.1004-1G>A p.X335_splice | Splice Site (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99711462; called by muse, mutect2, varscan2
- ARHGAP20 | c.1400T>G p.I467R | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99505712; called by muse, mutect2, varscan2
- ATRN | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV99497969; called by muse, mutect2, varscan2
- AWAT2 | c.195A>T p.R65= | Splice Region (SNP) | VAF 17/24 reads (71%) | catalogued as COSV99339820; called by muse, mutect2, varscan2
- B2M | c.192G>C p.E64D | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100837719, COSV62565329; called by muse, mutect2, varscan2
- B3GAT3 | c.446A>G p.E149G | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99606175; called by muse, mutect2, varscan2
- C9orf131 | c.3043C>A p.P1015T | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV100398176; called by muse, mutect2, varscan2
- CAMKV | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs865944634, COSV56554265; called by muse, mutect2, varscan2
- CBFA2T2 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.904); catalogued as COSV100656569; called by muse, mutect2, varscan2
- CBWD1 | c.478A>G p.I160V | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as rs1426157678, COSV100071366; called by muse, mutect2, varscan2
- CCNY | c.379A>T p.I127L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV99591261; called by muse, mutect2, varscan2
- CDC37L1 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101116680; called by muse, mutect2, varscan2
- CDH24 | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as COSV99400509; called by muse, mutect2, varscan2
- CDH9 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs778204468, COSV50488840; called by muse, mutect2, varscan2
- CDKN2A | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100448219, COSV58684018; called by muse, varscan2
- CEP104 | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs535293642, COSV100986750; called by muse, mutect2
- CLGN | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100346881; called by muse, mutect2, varscan2
- CNKSR2 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as rs770547746, COSV99670195; called by muse, mutect2, varscan2
- COMTD1 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.143); catalogued as rs1432611438, COSV100041158, COSV100041167; called by muse, mutect2, varscan2
- CSMD3 | c.8606C>T p.S2869F (on ENST00000297405 / NM_001363185.1; = p.S2700F on NM_052900.3) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.648); catalogued as COSV99828977; called by muse, mutect2
- CSNK1G2 | c.796A>C p.K266Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99730318; called by muse, mutect2
- CTC1 | c.3607G>C p.E1203Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100236896; called by muse, mutect2, varscan2
- DCC | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.464); catalogued as COSV59113201; called by muse, mutect2, varscan2
- DCLK1 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as COSV99713539; called by muse, mutect2, varscan2
- DCPS | c.853T>A p.F285I | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs1177335027, COSV99703632; called by muse, mutect2, varscan2
- DNAJC28 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.472); catalogued as COSV100074786; called by muse, mutect2, varscan2
- DNM2 | c.904A>T p.S302C | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100118205; called by muse, mutect2, varscan2
- DTNB | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99978166; called by muse, mutect2, varscan2
- DUSP26 | c.378G>A p.M126I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.02); catalogued as rs1173101925, COSV99823613; called by muse, mutect2, varscan2
- EIF6 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55773001; called by muse, mutect2, varscan2
- ERMP1 | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV99284851; called by muse, mutect2, varscan2
- EYA3 | c.407C>A p.T136N | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100870307; called by muse, mutect2, varscan2
- EYS | c.1058A>T p.D353V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.521); catalogued as COSV100676953, COSV100677288; called by muse, varscan2
- FAT1 | c.9126C>G p.I3042M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs773557171, COSV101499690; called by muse, mutect2, varscan2
- FAT1 | c.7265T>A p.I2422K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101499691; called by muse, mutect2, varscan2
- GABRA6 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.553); catalogued as COSV99195370; called by muse, mutect2, varscan2
- GALNTL6 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101487914; called by muse, mutect2, varscan2
- GDPD3 | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99532196; called by muse, mutect2, varscan2
- GOLGB1 | c.7978G>A p.E2660K | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as rs1392114489, COSV100511660; called by muse, mutect2, varscan2
- H3C2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.204); catalogued as rs1332600888, COSV52518397, COSV52518528; called by muse, mutect2, varscan2
- HECTD1 | c.6207C>A p.S2069R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.282); catalogued as COSV101237566; called by muse, mutect2, varscan2
- HORMAD1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); catalogued as COSV100464543; called by muse, mutect2, varscan2
- HOXD4 | c.597G>C p.K199N | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100107010, COSV100107094; called by muse, mutect2, varscan2
- INTS7 | c.2468A>G p.N823S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100877597; called by muse, mutect2, varscan2
- INTS9 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV101273872; called by muse, mutect2, varscan2
- IPP | c.603C>G p.F201L | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV100739745; called by muse, mutect2, varscan2
- ITGB6 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV51790647, COSV99325115; called by muse, mutect2, varscan2
- JPT2 | c.80T>G p.L27R | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV99936314; called by muse, mutect2, varscan2
- KIF13A | c.2927G>A p.R976K | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV99438805; called by muse, mutect2, varscan2
- KNL1 | c.3998A>T p.N1333I (on ENST00000346991 / NM_170589.5; = p.N1307I on NM_144508.5) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100707164; called by muse, mutect2, varscan2
- KRT86 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs752176981, COSV53291769, COSV99525143; called by muse, mutect2, varscan2
- LRRC10 | c.348G>C p.E116D | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV100825537; called by muse, mutect2, varscan2
- LRRTM1 | c.594G>C p.K198N | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV99703361; called by muse, mutect2, varscan2
- MAGEA12 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100757105, COSV63295013; called by muse, mutect2, varscan2
- MAGEB6 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 68/101 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1413833390, COSV66872246; called by muse, mutect2, varscan2
- MAP3K14 | c.1787G>A p.W596* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100766588; called by muse, mutect2, varscan2
- MAP3K7 | c.899A>G p.Y300C | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100997567; called by muse, mutect2
- MEX3C | c.684G>C p.K228N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs748375694, COSV101346350; called by muse, varscan2
- MLYCD | c.1299C>G p.I433M | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV52305873, COSV99299493; called by muse, mutect2, varscan2
- MMP16 | c.1553A>G p.E518G | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV99690853; called by muse, mutect2, varscan2
- MOV10 | c.1814A>T p.Y605F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99588587; called by muse, mutect2, varscan2
- MYL10 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as rs373940709, COSV56207463, COSV99781156; called by muse, mutect2, varscan2
- MYOF | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 85/355 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100826215; called by muse, mutect2, varscan2
- NAA25 | c.2779G>C p.D927H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV99928161; called by muse, mutect2, varscan2
- NACC1 | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); catalogued as rs1166608140, COSV52834591, COSV99457360; called by muse, mutect2, varscan2
- NF2 | c.1575-1G>A p.X525_splice | Splice Site (SNP) | VAF 75/125 reads (60%) | catalogued as CS961644, CS982294, COSV58520503, COSV58526843; called by muse, mutect2, varscan2
- NOMO1 | c.2809C>T p.P937S | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55060803; called by muse, mutect2, varscan2
- NOTCH1 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 43/67 reads (64%) | catalogued as COSV53045503, COSV99492623; called by muse, mutect2, varscan2
- NPAS3 | c.187C>T p.R63C (on ENST00000356141 / NM_001164749.2; = p.R33C on NM_022123.3) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100385342, COSV58094126; called by muse, mutect2, varscan2
- OR51G2 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs771596766, COSV58991831; called by muse, mutect2, varscan2
- PAN3 | c.1496A>T p.N499I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.72); catalogued as COSV99145292; called by muse, mutect2, varscan2
- PAPPA | c.891G>T p.W297C | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100075677; called by muse, mutect2, varscan2
- PCDH7 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.929); catalogued as COSV100688748; called by muse, mutect2, varscan2
- PCNT | c.9701-1G>C p.X3234_splice | Splice Site (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100856167; called by muse, mutect2, varscan2
- PITX2 | c.407G>A p.R136H (on ENST00000354925 / NM_001204397.1; = p.R143H on NM_000325.6) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM024244, COSV100146552, COSV60740376, COSV60741497; called by muse, mutect2, varscan2
- PKHD1 | c.9431T>C p.I3144T | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100584891; called by muse, mutect2, varscan2
- PNMA8A | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100562455; called by muse, mutect2, varscan2
- POP4 | c.282G>A p.Q94= | Splice Region (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99694657; called by muse, mutect2, varscan2
- POU6F2 | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.843); catalogued as COSV101302902; called by muse, mutect2, varscan2
- PREPL | c.2066A>G p.N689S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.99); PolyPhen benign (0.066); catalogued as rs760875859, COSV99576562; called by muse, mutect2, varscan2
- PRKCQ | c.1111C>G p.L371V | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54116267, COSV99578108; called by muse, mutect2, varscan2
- PROX1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV99800394, COSV99800422; called by muse, mutect2, varscan2
- RAD18 | c.1139C>G p.S380C | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.415); catalogued as COSV99368903; called by muse, mutect2, varscan2
- RBM19 | c.2477C>T p.P826L | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1033500017, COSV99926960; called by muse, mutect2, varscan2
- REG3A | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.376); catalogued as COSV100532960; called by muse, mutect2, varscan2
- RIC8B | c.1217G>C p.R406T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100822751; called by muse, mutect2, varscan2
- RNF182 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV101337982; called by muse, mutect2, varscan2
- RYR2 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV100769956, COSV100773281; called by muse, mutect2, varscan2
- SAP30BP | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV99503090; called by muse, mutect2, varscan2
- SETX | c.5306G>C p.R1769T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV99810502, COSV99811260; called by muse, mutect2, varscan2
- SGO2 | c.2082G>T p.Q694H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV100764824; called by muse, mutect2, varscan2
- SHOX | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100479344; called by muse, mutect2, varscan2
- SHPRH | c.1867T>G p.F623V | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV99262840; called by muse, mutect2, varscan2
- SLITRK1 | c.78G>C p.E26D | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV101000103; called by muse, mutect2, varscan2
- SMURF1 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1355433444, COSV100742702; called by muse, mutect2, varscan2
- SMYD4 | c.1313A>G p.E438G | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as COSV100563296; called by muse, mutect2, varscan2
- SOBP | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1423116770, COSV100432927, COSV100433499; called by muse, mutect2, varscan2
- SPRTN | c.1443C>G p.I481M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV99150191; called by muse, mutect2, varscan2
- SPTB | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV101072476; called by muse, mutect2, varscan2
- STAT4 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100636270, COSV104422238; called by muse, mutect2, varscan2
- STRA8 | c.244C>T p.L82F (on ENST00000275764; = p.L60F on NM_182489.2) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV99312711; called by muse, mutect2, varscan2
- STRIP2 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV99974251; called by muse, mutect2, varscan2
- STX11 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100845545; called by muse, mutect2, varscan2
- STXBP5L | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs748974536, COSV56520934; called by muse, mutect2, varscan2
- SULF2 | c.1192C>A p.R398= | Splice Region (SNP) | VAF 78/294 reads (27%) | catalogued as COSV100737504, COSV63415105, COSV63415152; called by muse, mutect2, varscan2
- SYNPO2L | c.1961C>T p.S654L (on ENST00000394810 / NM_001114133.3; = p.S430L on NM_024875.5) | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100866491; called by muse, mutect2, varscan2
- TASOR2 | c.2429C>T p.S810F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1158262944, COSV100051225; called by muse, mutect2
- TG | c.7241G>C p.G2414A | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99603840; called by muse, mutect2, varscan2
- TLN1 | c.2645A>C p.D882A | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV100148362; called by muse, mutect2, varscan2
- TMPPE | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 76/124 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs1427018847, COSV100257774; called by muse, mutect2, varscan2
- TNRC18 | c.3523C>G p.L1175V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.13); catalogued as COSV101269632, COSV101269911; called by muse, mutect2, varscan2
- TOE1 | c.751T>C p.C251R | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV100517823; called by muse, mutect2, varscan2
- TPH2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV61590278; called by muse, mutect2, varscan2
- TTN | c.20975G>A p.G6992E (on ENST00000591111; = p.G6065E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | PolyPhen probably damaging (0.993); catalogued as COSV100627067, COSV59888248; called by muse, mutect2, varscan2
- UTP14A | c.1842A>T p.E614D | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.05); PolyPhen benign (0.345); catalogued as COSV100929026; called by muse, mutect2, varscan2
- VPS13A | c.2863G>C p.D955H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100653792; called by muse, mutect2, varscan2
- ZBTB21 | c.2058G>T p.K686N | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100177406; called by muse, mutect2, varscan2
- ZBTB3 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV67361981; called by muse, mutect2, varscan2
- ZBTB3 | c.103T>C p.F35L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101189018; called by muse, mutect2, varscan2
- ZFP2 | c.863A>G p.H288R | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100797147; called by muse, mutect2, varscan2
- ZMYM1 | c.2345G>C p.G782A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV100721106; called by muse, mutect2, varscan2
- ZMYM1 | c.2816G>A p.R939K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV100721107; called by muse, mutect2, varscan2
- ZNF112 | c.1746A>T p.K582N (on ENST00000337401 / NM_001083335.2; = p.K576N on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV100496412; called by muse, mutect2, varscan2
- ZNF33B | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100847815; called by muse, mutect2
- ZNF45 | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99524300; called by muse, mutect2, varscan2
- ZNF670 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs1427040177, COSV100829163, COSV100829376; called by muse, mutect2, varscan2
- ZNF91 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV100323594; called by muse, mutect2, varscan2
- ZSCAN20 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100792770, COSV63682169; called by muse, mutect2, varscan2
- ACACA | c.3529C>G p.H1177D | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF6 | c.553del p.D185Tfs*18 | Frame Shift Del (DEL) | VAF 68/135 reads (50%) | called by mutect2, pindel, varscan2
- FRG2C | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.848); called by muse, mutect2
- HUWE1 | c.6821_6824del p.K2274Mfs*55 | Frame Shift Del (DEL) | VAF 35/68 reads (51%) | called by mutect2, pindel, varscan2
- NFAT5 | c.3194_3203del p.S1065Wfs*80 | Frame Shift Del (DEL) | VAF 33/126 reads (26%) | called by mutect2, pindel, varscan2
- PIGG | c.2409_2411del p.L804del (on ENST00000453061 / NM_001127178.3; = p.L796del on NM_017733.4) | In Frame Del (DEL) | VAF 48/178 reads (27%) | called by pindel, varscan2
- TNK1 | c.1604dup p.L536Pfs*10 (on ENST00000576812 / NM_001251902.2; = p.L531Pfs*10 on NM_003985.5) | Frame Shift Ins (INS) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- TOX2 | c.91_103del p.R31Lfs*18 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- TRAV29DV5 | c.243T>G p.D81E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF605 | c.1273C>G p.Q425E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY1 | c.2970C>T p.G990= | Silent (SNP) | VAF 52/123 reads (42%) | catalogued as rs1204025969, COSV99813096; called by muse, mutect2, varscan2
- AGGF1 | c.1491C>T p.Y497= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs753617211, COSV57227931; called by muse, mutect2, varscan2
- AKAP9 | c.11709T>C p.Y3903= (on ENST00000359028; = p.Y3879= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99134222; called by muse, mutect2, varscan2
- ALDH2 | c.483C>A p.I161= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99923344; called by muse, mutect2, varscan2
- ASAP2 | c.1005G>C p.L335= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99857033; called by muse, mutect2, varscan2
- BSX | c.657C>T p.D219= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV58005106; called by muse, mutect2, varscan2
- CACNB3 | c.1056C>T p.Y352= | Silent (SNP) | VAF 58/212 reads (27%) | catalogued as COSV99975167; called by muse, mutect2, varscan2
- CCN4 | c.372C>T p.V124= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as COSV99137565; called by muse, mutect2, varscan2
- CFAP91 | c.453C>G p.L151= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99847594; called by muse, mutect2
- CLDN5 | c.288C>T p.F96= (on ENST00000618236 / NM_001363066.2; = p.F181= on NM_003277.4) | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs1307894263, COSV99597122; called by muse, mutect2
- CXXC5 | c.759C>T p.I253= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV100210885; called by muse, mutect2, varscan2
- CXXC5 | c.897C>G p.L299= | Silent (SNP) | VAF 44/193 reads (23%) | catalogued as COSV100210888; called by muse, mutect2, varscan2
- CYFIP1 | c.168C>T p.I56= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs745649616; called by muse, mutect2, varscan2
- DCAF1 | c.279G>C p.V93= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100245058; called by muse, mutect2, varscan2
- DNAH10 | c.6078C>T p.I2026= (on ENST00000409039; = p.I1965= on NM_207437.3) | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV101292968; called by muse, mutect2, varscan2
- ELAPOR1 | c.1125G>C p.V375= | Silent (SNP) | VAF 38/169 reads (22%) | catalogued as COSV100884498; called by muse, mutect2, varscan2
- ELP3 | c.987T>C p.Y329= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99834258; called by muse, mutect2, varscan2
- ITGA4 | c.789G>A p.Q263= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99276949; called by muse, mutect2
- KANSL1 | c.961C>T p.L321= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV99295065; called by muse, mutect2, varscan2
- KCNK1 | c.477C>T p.H159= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs143943031; called by muse, mutect2, varscan2
- KIAA2026 | c.3333G>C p.V1111= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV101199247; called by muse, mutect2, varscan2
- KRTAP11-1 | c.69G>A p.V23= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV100190877; called by muse, mutect2, varscan2
- MCM10 | c.2613G>C p.L871= (on ENST00000484800 / NM_182751.3; = p.L870= on NM_018518.5) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs755773867, COSV101098564; called by muse, mutect2, varscan2
- MDN1 | c.8769C>T p.H2923= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV101021923; called by muse, mutect2, varscan2
- MYOT | c.291C>G p.L97= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV99525151; called by muse, mutect2, varscan2
- NIBAN2 | c.1131C>T p.I377= | Silent (SNP) | VAF 67/164 reads (41%) | catalogued as COSV100964987; called by muse, mutect2, varscan2
- NKIRAS1 | c.324A>G p.K108= | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as COSV101174746; called by muse, mutect2, varscan2
- NKX2-5 | c.891C>T p.V297= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs750356140, COSV100234935; called by muse, mutect2, varscan2
- NLRP10 | c.960G>A p.R320= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV100150027; called by muse, mutect2, varscan2
- PCDHA13 | c.327C>T p.I109= | Silent (SNP) | VAF 65/200 reads (33%) | catalogued as COSV99170188; called by muse, mutect2, varscan2
- PKHD1 | c.9432C>T p.I3144= | Silent (SNP) | VAF 62/215 reads (29%) | catalogued as COSV100584890, COSV100585237; called by muse, mutect2, varscan2
- PNPLA4 | c.525C>T p.V175= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV101124445; called by muse, mutect2, varscan2
- PRRC2A | c.4395G>A p.L1465= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV101051404; called by muse, mutect2, varscan2
- SLC25A42 | c.489G>A p.P163= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100588260; called by muse, mutect2, varscan2
- SOGA1 | c.1752C>T p.S584= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99415921; called by muse, mutect2
- STAT5A | c.1122C>T p.I374= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV100604875, COSV61805815, COSV61808933; called by muse, mutect2, varscan2
- SVEP1 | c.6771G>C p.L2257= | Silent (SNP) | VAF 56/234 reads (24%) | catalogued as COSV99930051; called by muse, mutect2, varscan2
- SYT4 | c.330C>G p.L110= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV99674562; called by muse, mutect2, varscan2
- TENT5A | c.549C>G p.L183= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100199218; called by muse, mutect2, varscan2
- UBE3B | c.1002C>T p.F334= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs543547516, COSV55093949; called by muse, mutect2, varscan2
- VWF | c.6210G>T p.L2070= | Silent (SNP) | VAF 43/141 reads (30%) | catalogued as COSV99780539; called by muse, mutect2, varscan2
- WDR5B | c.540C>A p.S180= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV100413193; called by muse, mutect2, varscan2
- YY2 | c.498G>A p.T166= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV63411534; called by muse, mutect2, varscan2
- ZNF835 | c.1284C>T p.S428= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs966386046, COSV101606418, COSV73379769; called by muse, mutect2, varscan2
- CCAR1 | c.-1C>G | 5'UTR (SNP) | VAF 27/104 reads (26%) | catalogued as COSV56269193, COSV99771509; called by muse, mutect2, varscan2
- CHCHD2P9 | n.279G>A | RNA (SNP) | VAF 9/36 reads (25%) | catalogued as rs750230884; called by muse, mutect2, varscan2
- PCDHA2 | c.2388+46A>T | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as rs782637253, COSV100974190, COSV100974198; called by muse, mutect2, varscan2
- PIK3C2B | c.*130C>G | 3'UTR (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100916038, COSV100916254; called by muse, mutect2, varscan2
